Somatic mutation profile of tumor specimen TCGA-3B-A9HY-01A (aliquot TCGA-3B-A9HY-01A-11D-A38Z-09) from TCGA case TCGA-3B-A9HY, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 49.6 years (18,109 days).
Specimen TCGA-3B-A9HY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 143f10ed-1d42-4dba-aac3-3291a973bb2e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3B-A9HY-10A (Blood Derived Normal), aliquot TCGA-3B-A9HY-10A-01D-A38Z-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d18c416a-9b14-4fc7-af5d-e7d80a64371b

The open-access MAF lists 54 somatic variants for this specimen: 38 protein-altering or splice-affecting, 16 silent.
By variant classification: Missense Mutation 33, Silent 16, Nonsense Mutation 3, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.1510C>T p.Q504* | Nonsense Mutation (SNP) | VAF 18/20 reads (90%) | catalogued as rs886043247, CM030506, COSV57295964, COSV99927064; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 15/21 reads (71%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACAN | c.2437C>T p.P813S | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated (0.35); PolyPhen benign (0.118); catalogued as COSV61355052; called by muse, mutect2, varscan2
- CNTNAP5 | c.215C>A p.S72Y | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101443486; called by muse, mutect2, varscan2
- DIS3L2 | c.1459C>T p.R487C | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.224); catalogued as rs376340398; called by mutect2, varscan2
- DOCK7 | c.767T>A p.I256K | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.171); catalogued as COSV99224250; called by muse, mutect2, varscan2
- EPS15L1 | c.507C>G p.D169E | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.68); PolyPhen benign (0.162); catalogued as COSV99932995; called by muse, mutect2, varscan2
- FNDC3A | c.424G>T p.G142* (on ENST00000492622 / NM_001079673.2; = p.G86* on NM_014923.5) | Nonsense Mutation (SNP) | VAF 3/50 reads (6%) | catalogued as COSV101001246; called by muse, mutect2
- GTF3C2 | c.1631G>T p.G544V | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99272683; called by muse, mutect2
- HRNR | c.1193C>T p.S398F | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as COSV100913426; called by muse, mutect2, varscan2
- HS3ST5 | c.236A>C p.E79A | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.014); catalogued as rs370563140; called by muse, varscan2
- HS3ST5 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.37); PolyPhen benign (0.01); catalogued as COSV100450809, COSV57138489; called by muse, mutect2, varscan2
- KIAA1549L | c.4151C>T p.S1384L (on ENST00000321505; = p.S1681L on NM_012194.3) | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as rs1421739831, COSV58594901; called by muse, mutect2, varscan2
- KRTAP13-1 | c.97A>C p.N33H | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.269); catalogued as COSV100819869; called by muse, mutect2, varscan2
- LIPA | c.379C>T p.R127W | Missense Mutation (SNP) | VAF 26/33 reads (79%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs140686447; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRP12 | c.722G>A p.G241E | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99407649; called by muse, mutect2, varscan2
- LRP12 | c.721G>A p.G241R | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99407652; called by muse, mutect2, varscan2
- LRTM2 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.179); catalogued as COSV54564353; called by muse, mutect2, varscan2
- MAGEE2 | c.172A>C p.T58P | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV100973068, COSV64897185; called by muse, mutect2, varscan2
- MYH8 | c.3587G>A p.R1196Q | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1340594495, COSV101238166, COSV67972640; called by muse, mutect2, varscan2
- NCKAP5L | c.1775C>A p.P592Q | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.12); catalogued as COSV100258722; called by muse, mutect2
- OTOF | c.1173G>C p.K391N | Missense Mutation (SNP) | VAF 23/27 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99717536; called by muse, mutect2, varscan2
- PCDHA4 | c.802G>C p.D268H | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100793396; called by muse, mutect2, varscan2
- PCDHA4 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100793397; called by muse, varscan2
- PCDHA4 | c.1711G>C p.G571R | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.006); catalogued as COSV100793400; called by muse, mutect2, varscan2
- PLCE1 | c.3545G>A p.S1182N | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV99594749; called by muse, mutect2, varscan2
- PSG1 | c.45G>A p.W15* | Nonsense Mutation (SNP) | VAF 35/71 reads (49%) | catalogued as COSV54948466; called by muse, mutect2, varscan2
- RESF1 | c.1085A>C p.Q362P | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as COSV100440317; called by muse, mutect2, varscan2
- RP1 | c.3662C>T p.P1221L | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.086); catalogued as COSV55115221; called by muse, mutect2, varscan2
- SLCO1C1 | c.1997A>C p.K666T | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as COSV99859047; called by muse, mutect2, varscan2
- TCEA2 | c.277G>A p.G93S | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs982140071, COSV100200342; called by muse, mutect2, varscan2
- TCEA2 | c.278G>A p.G93D | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100200343; called by muse, mutect2, varscan2
- TDRD9 | c.3858T>C p.V1286= | Splice Region (SNP) | VAF 23/49 reads (47%) | catalogued as COSV100175071; called by muse, mutect2, varscan2
- TG | c.4379T>G p.V1460G | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1251802652, COSV99600622; called by muse, mutect2, varscan2
- THAP4 | c.145C>A p.P49T | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV101126027; called by muse, mutect2, varscan2
- WDR18 | c.925C>T p.L309F | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT tolerated (0.16); PolyPhen benign (0.14); catalogued as COSV99242823; called by muse, mutect2, varscan2
- WIPF1 | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.842); catalogued as COSV99768591; called by muse, mutect2, varscan2
- EFCAB6 | c.3348del p.K1116Nfs*2 | Frame Shift Del (DEL) | VAF 23/86 reads (27%) | called by mutect2, pindel, varscan2
- ABCA13 | c.14619G>A p.G4873= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV101291323, COSV68944934; called by muse, mutect2, varscan2
- ANGPT4 | c.1380A>T p.S460= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as COSV101124723; called by muse, mutect2, varscan2
- BCL11A | c.2079T>A p.G693= (on ENST00000335712 / NM_001365609.1; = p.G727= on NM_018014.4) | Silent (SNP) | VAF 13/16 reads (81%) | catalogued as COSV100185606; called by muse, mutect2, varscan2
- CENPE | c.1680G>A p.K560= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV99477804; called by muse, mutect2, varscan2
- JAKMIP1 | c.1383A>G p.T461= | Silent (SNP) | VAF 24/73 reads (33%) | catalogued as COSV51539126, COSV99289459; called by muse, mutect2, varscan2
- KPNA6 | c.445C>T p.L149= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as COSV101012493; called by muse, mutect2, varscan2
- LTBP2 | c.2277G>A p.R759= | Silent (SNP) | VAF 24/46 reads (52%) | catalogued as rs748254247, COSV100000221; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYH8 | c.3588G>A p.R1196= | Silent (SNP) | VAF 10/14 reads (71%) | catalogued as COSV67973789; called by muse, mutect2, varscan2
- OR8B12 | c.534T>C p.C178= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as COSV100172776; called by muse, mutect2, varscan2
- PALMD | c.1131G>A p.G377= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as COSV54166697; called by muse, mutect2, varscan2
- PCDHA4 | c.162G>A p.L54= | Silent (SNP) | VAF 28/71 reads (39%) | catalogued as COSV100793395; called by muse, mutect2, varscan2
- PIWIL2 | c.783G>A p.L261= | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as COSV100769377; called by muse, mutect2, varscan2
- PLXNB2 | c.4614G>A p.R1538= | Silent (SNP) | VAF 22/47 reads (47%) | catalogued as rs1438344711, COSV100834036; called by muse, mutect2, varscan2
- TFRC | c.1557G>T p.G519= | Silent (SNP) | VAF 32/83 reads (39%) | catalogued as COSV100786451; called by muse, mutect2, varscan2
- TP53 | c.741C>T p.N247= | Silent (SNP) | VAF 14/21 reads (67%) | catalogued as rs786202448, COSV52772996, COSV52808615, COSV52847658; ClinVar: likely benign; called by muse, mutect2, varscan2
- WDR18 | c.924C>T p.A308= | Silent (SNP) | VAF 8/10 reads (80%) | catalogued as COSV99242821; called by muse, mutect2, varscan2
